Surgical pathology report (de-identified scan), TCGA case TCGA-24-0982, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-0982-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

Physician(s):

Other Related Clinical Data:

DIAGNOSIS:

OMENTUM, OMENTECTOMY

- METASTATIC SEROUS ADENOCARCINOMA, LARGEST IMPLANT MEASURING 27 CM

SOFT TISSUE, "RIGHT HEMI-DIAPHRAGM," BIOPSY

- DETACHED FRAGMENTS OF SEROUS ADENOCARCINOMA WITHIN BLOOD AND FIBRIN

SOFT TISSUE, "PELVIC TUMOR," EXCISION

- SEROUS ADENOCARCINOMA

OVARY, LEFT, SALPINGO-OOPHORECTOMY

- SEROUS ADENOCARCINOMA WITH INVOLVEMENT OF OVARIAN SURFACE

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY

- SEROUS ADENOCARCINOMA, INTRATUBAL AND PARATUBAL

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- SEROUS ADENOCARCINOMA WITH INVOLVEMENT OF OVARIAN SURFACE

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- SEROUS ADENOCARCINOMA WITHIN PARATUBAL SOFT TISSUE BY DIRECT EXTENSION

UTERUS, HYSTERECTOMY

- SEROSAL INVOLVEMENT BY METASTATIC SEROUS ADENOCARCINOMA

- MYOMETRIUM WITH LEIOMYOMATA, LARGEST MEASURING 1.5 CM

- INACTIVE ENDOMETRIUM

- CHRONIC CERVICITIS WITH FOCAL MUCOSAL EROSION

"LYMPH NODE, PELVIC," BIOPSY

- SEROUS ADENOCARCINOMA (SEE COMMENT)

SOFT TISSUE, LEFT PERITONEUM, BIOPSY

- MATURE FIBROADIPOSE TISSUE

- NO EVIDENCE OF MALIGNANCY

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides(and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

[page 2 of 4]
Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as:

"Called to OR to pick up 'left adnexa.' The specimen consists of a segment of fallopian tube (5.5 x 0.7 cm) with attached focally necrotic, fleshy mass (9 x 7 x 5 cm). It weighs 115 grams. Tissue removed for and tumor bank. Called again to pick up and open 'uterus and cervix.' The specimen measures 3 cm from cornu-to-cornu by 8 cm from fundus to os by 3 cm from anterior to posterior, and weighs 49 grams. Opened to show a smooth-lined endometrial cavity measuring 1.5 x 3 cm," by

Microscopic Description and Comment:

Histologic sections of the right and left ovaries show a poorly differentiated serous adenocarcinoma which invades into the mesovarian and paratubal soft tissues. Metastatic serous adenocarcinoma is identified on the serosal surface of the uterus, the omentum, and in tissue designated as a pelvic lymph node, although no lymphoid tissue is identified.

)

History:

The patient is a year old woman with ovarian cancer. Operative procedure: Total abdominal hysterectomy and bilateral salpingo-oophorectomy with tumor debulking.

Specimen(s) Received:

- A: OMENTUM
- B: RIGHT HEMI-DIAPHRAGM
- C: PELVIC TUMOR
- D: LEFT ADNEXA
- E: RIGHT ADNEXA
- F: UTERUS AND CERVIX
- G: PELVIC NODE
- H: LEFT PERITONEUM

Gross Description

The specimen is received in eight formalin-filled containers, each labeled with the patient's name

The first container is labeled "omentum."

It contains three pieces of omentum measuring 5, 6, and 27 cm in greatest dimension. All appear to be caked with white, firm tumor. The largest piece of omentum is essentially entirely replaced by tumor. Labeled A1. Jar 3.

The second container is labeled, "right hemidiaphragm." It contains an irregularly-shaped strip of brown tissue measuring 7 cm by an average width of 1.4 cm. No tumor is identified grossly. Labeled B1 to B5. Jar 0.

The third container is labeled, "pelvic tumor." It contains multiple fragments of tan-white-gray friable tissue ranging in size from 1 cm to 5.5 cm in greatest dimension. One piece has what looks like numerous papillary excrescences. Labeled C1 to C6. Jar 2.

The fourth container is labeled, "left adnexa." It contains a cystic piece of tissue with attached fallopian tube, both with dimensions consistent with those in the intraoperative consult. The cystic part is involved by a papillary lesion with abundant necrosis. The paratubal soft tissue appears grossly involved by this tumor. Labeled D1 to D5-tumor, D6 and D7-fallopian tube with tumor. Jar 2.

The fifth container is labeled, "right adnexa." It contains a cystic piece of tissue with adjacent fallopian tube. The cystic portion measures 7 x 7 x 3 cm. The accompanying fallopian tube measures 4.5 x 0.6 cm. The cystic part is diffusely involved by necrotic, tan-gray tumor which appears to involve the

[page 3 of 4]
peritoneal-lined surface. The fallopian tube has a tan-white tumor implant adjacent to it. A second fragment of tissue measuring 5 x 4 x 3 cm shows similar necrotic tissue. Labeled E1 to E4-cystic part of larger fragment, E5-smaller fragment of tissue, E6-tumor implant near fallopian tube. Jar 2. The sixth container is labeled, "uterus and cervix." It contains a previously-bivalved uterus with weight and dimensions consistent with those in the intraoperative consult. The ectocervix measures 3 cm in diameter. It is tan-gray and grossly unremarkable. The endocervical canal measures 2 cm x 0.6 cm and is lined by tan-brown, grossly unremarkable mucosa. The endometrial cavity with dimensions consistent with those in the intraoperative consult is lined by tan-brown, grossly unremarkable mucosa. The myometrium varies in thickness from 0.5 to 1.5 cm and has a myomatous lesion measuring 1.5 cm in greatest dimension. Cut surface of this lesion is tan-gray and trabecular. There are no areas of hemorrhage or necrosis within the lesion. Two additional intramural myomatous lesions are identified measuring 0.3 cm and 0.5 cm. The serosal surface of the uterus is grossly suspicious for involvement by tumor. Labeled F1-anterior cervix, F2-anterior endometrium, F3-posterior cervix, F4-posterior endometrium, F5-myomatous lesion, F6 and F7-serosal surface suspicious for involvement by tumor. Jar 2. The seventh container is labeled, "pelvic node." It contains a lymph node measuring 2.5 x 1.7 x 0.8 cm. It is grossly suspicious for involvement by tumor. Labeled G1 and G2. Jar 0.

The eighth container is labeled, "left peritoneum." It contains a piece of fibroadipose tissue measuring 6 cm x 1.5 x 1 cm. It is grossly unremarkable. Labeled H1 and H2. Jar 0.

Synopsis

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT
2. The HISTOLOGIC DIAGNOSIS is:
Serous adenocarcinoma
3. The LOCATION OF THE PRIMARY TUMOR is:
Indeterminate
4. The FIGO GRADE of the tumor is:
II (Tumor composed of 5-50% solid cellular nests)
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated)
6. Tumor IS identified on the ovarian surfaces.
7. Tumor DOES invade the mesovarium.
8. Tumor DOES NOT invade the adjacent fallopian tube but does invade the paratubal soft tissue.
9. Tumor DOES invade the pelvic soft tissue.
10. Tumor involvement of the pelvic peritoneum is PRESENT.
11. Metastatic involvement of the EXTRAPELVIC PERITONEUM is PRESENT.
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true pelvis is 27 cm
14. Metastatic involvement of the uterine serosa is PRESENT.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases are indeterminate.
17. The total number of regional lymph nodes examined is 0

[page 4 of 4]
18. The total number of metastatically-involved regional lymph nodes is indeterminate

19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition	
T3c		IIIC	Macroscopic
peritoneal metastasis beyond true pelvis			
measuring > 2 cm in greatest dimension.			

THE REGIONAL LYMPH NODES are classified as:

NX (Status cannot be assessed)

THE STATUS OF DISTANT TUMOR SITES is classified as:

MX (Status cannot be assessed)

20. The FINAL AJCC/UICC/FIGO STAGE IS:

AJCC/UICC/FIGO

IIIC

(Any T/NX/MX)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 632e1145-6b3d-4154-b2ab-26b35d4586ee (TCGA-24-0982.75BE9FE6-5606-4F29-A08F-69E3F50912D0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).